Somatic mutation profile of tumor specimen TARGET-30-PARAMT-01A (aliquot TARGET-30-PARAMT-01A-01D) from TARGET case TARGET-30-PARAMT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.4 years (885 days).
Specimen TARGET-30-PARAMT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92463c92-9b8b-4b5b-9b38-58224f812c56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARAMT-10A (Blood Derived Normal), aliquot TARGET-30-PARAMT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/426b5487-7937-4915-8974-e6e5b11f549d

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.2375C>G p.T792R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV67135577; called by muse, mutect2, varscan2
- AGPAT5 | c.1024A>G p.R342G | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV53448284; called by muse, mutect2, varscan2
- CLCA1 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs746147234, COSV52327281, COSV52329453; called by muse, mutect2, varscan2
- COL5A1 | c.3583G>C p.G1195R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65672407; called by muse, mutect2, varscan2
- COMMD4 | c.313A>T p.S105C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV51190834; called by muse, mutect2, varscan2
- IFT88 | c.2485G>T p.D829Y (on ENST00000319980 / NM_001318493.2; = p.D820Y on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs532025198, COSV60675316; called by muse, mutect2, varscan2
- KIAA1958 | c.801C>G p.H267Q | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375048903, COSV61727208; called by muse, mutect2, varscan2
- MAP3K12 | c.801G>C p.K267N | Missense Mutation (SNP) | VAF 120/295 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57234558; called by muse, mutect2, varscan2
- MRPL55 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs555557877, COSV54342388, COSV99686909; called by muse, mutect2, varscan2
- NLRP3 | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60228694; called by muse, mutect2, varscan2
- PIFO | c.258+2T>A p.X86_splice | Splice Site (SNP) | VAF 17/51 reads (33%) | catalogued as COSV63864039; called by muse, mutect2, varscan2
- PTGDR | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60094571; called by muse, mutect2, varscan2
- RTN4 | c.3455C>T p.P1152L (on ENST00000337526 / NM_020532.5; = p.P159L on NM_007008.3) | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58271115; called by muse, mutect2, varscan2
- SERPINB11 | c.1118T>C p.F373S | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66957431, COSV66957524; called by muse, mutect2, varscan2
- UNC5B | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 216/454 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV58979091, COSV58980794; called by muse, varscan2
- VWA5A | c.2308G>C p.A770P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV64413725; called by muse, mutect2
- YAP1 | c.479T>A p.L160H | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV56777141; called by muse, mutect2, varscan2
- NUP210 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.82); called by muse, mutect2
- PRAMEF15 | c.1317G>T p.E439D | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC8E | c.939C>T p.A313= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs1244144229, COSV60718759; called by muse, mutect2, varscan2
- MEF2C | c.915A>G p.G305= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV60935383; called by muse, mutect2, varscan2
- RNF213 | c.8097G>A p.K2699= | Silent (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- UNC13C | c.3948G>T p.V1316= | Silent (SNP) | VAF 30/326 reads (9%) | catalogued as COSV52934336; called by muse, mutect2
